Somatic mutation profile of tumor specimen 0D9MK1 from CCDI case PBBISR, project CCDI-MCI: Molecular Characterization Initiative (MCI). Sex at birth: male; Primary diagnosis: Ependymoma, anaplastic; Tissue or organ of origin: Frontal lobe; Age at diagnosis: 15.7 years (5,739 days).
Specimen 0D9MK1: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) b7c2149f-d2db-4849-a531-089b86f3bcaa.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 0D9MK6 (Peripheral Whole Blood; tissue type Normal); read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/5d310cb2-93da-48ec-8e1a-82ada86f8bc8

The open-access MAF lists 9 somatic variants for this specimen: 5 protein-altering or splice-affecting, 3 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 5, Silent 3, Intron 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- RASGRF1 | c.1432C>T p.R478C | Missense Mutation (SNP) | VAF 57/530 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as rs1199183242, COSV69177307; called by muse, varscan2
- ZFYVE26 | c.3655C>A p.L1219I | Missense Mutation (SNP) | VAF 49/474 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV61333474; called by muse, varscan2
- CCDC177 | c.644C>T p.A215V | Missense Mutation (SNP) | VAF 196/705 reads (28%) | SIFT tolerated (0.21); PolyPhen benign (0.357); called by muse, varscan2
- ITGB6 | c.1697G>C p.R566T | Missense Mutation (SNP) | VAF 198/776 reads (26%) | SIFT tolerated (0.21); PolyPhen benign (0.009); called by muse, varscan2
- SYT5 | c.755C>T p.T252M | Missense Mutation (SNP) | VAF 473/1000 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.956); called by muse, varscan2
- IRS2 | c.3393C>T p.R1131= | Silent (SNP) | VAF 108/860 reads (13%) | called by muse, varscan2
- LPCAT1 | c.930G>A p.T310= | Silent (SNP) | VAF 570/1338 reads (43%) | catalogued as rs773176375; called by muse, varscan2
- NOS1 | c.3273G>A p.P1091= | Silent (SNP) | VAF 452/1104 reads (41%) | catalogued as rs1004551488, COSV57608306; called by muse, varscan2
- SIRT2 | c.692-40C>T | Intron (SNP) | VAF 112/300 reads (37%) | catalogued as rs759318266; called by muse, varscan2
